Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94D, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Barretos Cancer Hospital, specimen TCGA-YU-A94D-01A (Primary Tumor).

Collect date: _____
(MM/DD/YYYY)

PATHOLOGY REPORT:

ICD-O-3

*Teratoma, immature
malignant 908013*

*Date @ Testis NOS
0629*

3/5/14

PRIMARY SITE: Right testis

1-"Product of right radical orchiectomy":

Immature teratoma of the testis, characterized as follows:

- . Histologic grade III.
- . Infiltration of spermatic cord, tunica albuginea, epididymis and tunica vaginalis.
- . Presence of neural infiltration.
- . Presence of lymphatic vascular invasion.
- . Presence of sanguineous vascular invasion.
- . Spermatic cord margin is compromised.
- . Margin of tunica vaginalis is exiguous.

Source: NCI Genomic Data Commons file 32db93f1-ff3b-4978-b063-45dc13906435 (TCGA-YU-A94D.F6703532-A0D4-4A61-A760-80DFDA259ECA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).